Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MC-06A (Metastatic).

[page 1 of 3]
PathNet History Upload External
Client

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

ARCHIVAL HISTOPATHOLOGY SUPPLEMENTARY REPORT

Accession Number:

Collected Date: /

SUPPLEMENTARY HISTOPATHOLOGY REQUEST DETAIL

SUPPLEMENTARY REPORT

Documentation of the extent of extranodal spread was requested by Prof J
Thompson and Dr . The extranodal spread involves an area of 8 x 4.5mm
and extends to about 4.5mm beyond the edge of the lymph node (A).

Electronic signature

SUPPLEMENTARY SUMMARY / KEY WORDS

Lymph node - malignant melanoma, metastatic.
Haematopathology resection

1CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary

C77.3

lw
8/24/11

[page 2 of 3]
Requested by: N/A

MRN/Name:

Location: 1

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTES

Imm melanoma (R) hand ->

Now palp (R) axilla mass

SPECIMEN INFORMATION

(R) axillary dissection.

MACROSCOPIC DESCRIPTION

"Right axillary contents". An irregularly shaped piece of fatty tissue, 190 x 150 x 120mm, including some attached skeletal muscle, 80 x 70 x 25mm. The specimen was examined for lymph nodes working from the end with the skeletal muscle. Sectioning reveals a well-demarcated firm, pale grey nodule, 60 x 40 x 30mm, which extends to 4mm from the nearest margin. The nodule has extensive areas of necrosis and haemorrhage centrally. In addition there is a second nodule with a firm, white cut surface up to 25mm across and well clear of the surgical margins.

- A. Representative slice from largest nodule.
- B. Second nodule.
- C. 1 node in 3 pieces.
- D. 1 node in 2 pieces.
- E. 3 nodes.
- F. 4 nodes.
- G. 2 nodes.
- H. 1 node in 2 pieces.
- J&K. Each 4 nodes.
- L. 3 nodes.

MICROSCOPIC REPORT

"Right axillary contents". Sections show metastatic malignant melanoma involving 10 out of 26 lymph nodes. One of the involved nodes show extranodal tumour extension.

SEE ADDENDUM REPORT:

Electronic signature

verified by:

COMMENT

"Right axillary contents". Metastatic malignant melanoma in 10/26 lymph nodes.

SUMMARY / KEY WORDS

[page 3 of 3]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

Lymph node - malignant melanoma, metastatic
Haematopathology resection

Source: NCI Genomic Data Commons file 1cabd8ec-71c8-48c8-af7f-b1fd971736d9 (TCGA-EE-A2MC.3974002B-D305-46D6-B11C-BEE7260FA18B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).